Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A6S2, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A6S2-01A (Primary Tumor).

[page 1 of 4]
CCF ICD-O-3
Oligodendroglioma grade II
path 9450/3
Oligodendroglioma NOS
9450/3
Site Brain, supratentorial NOS
C71.0
JND 7/24/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: F Acct: Reported:
Physician(s):
Phy Location:

Clinical History

woman experiences headache, and on imaging has a 7 cm right medial frontal

lesion that

expands gyri, involves mid and anterior cingulate gurus, and is devoid of enhancement.

Operative Diagnoses

Brain tumor

Operation / Specimen

A: Cortical lesion, excision biopsy

B: Medial frontal tumor, excision biopsy

Pathologic Diagnosis

A. Bone, site not specified, excision: Lamellar bone, hyperostotic.

B. Brain, medial frontal, excision: Oligodendroglioma (WHO 2).

1p, 19q LOH (codeletion): Positive.

IDH1: Positive.

Methylated MGMT: Positive.

MIB-1 proliferation index: Up to 6%.

See Microscopy Description and Comment.

Comment

The sections contain portions of cerebrum that are focally slight to moderately infiltrated by a glial neoplastic

proliferation that has an oligodendroglial phenotype. There is one proliferation center where there is mitotic activity

and a MIB-1 proliferation index of 6%; the proliferation index elsewhere is up to about 2%. There is not endothelial

cell proliferation, microvascular cellular proliferation or tumor necrosis.

The neoplasm overall is a low histological grade oligodendroglioma (WHO 2). There is a proliferation center in which

there is a moderately heightened mitotic and cycling activity. As an isolated finding the meaning of these proliferation

centers is uncertain. They are not enough for upgrading the neoplasm; but may portend enhanced biological activity,

and may perhaps be precursors of transformation.

The morphological features of this tumor may be correlated with clinical, imaging, and operative findings for their

interpretation and patient's follow up.

Electronically Signed Out

Senior Staff Pathologist

Surgical Pathology

Page 2 of 4

Consultant:

Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

[page 2 of 4]
Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S548, D1S1592, D1S552, D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block DNA extracted from a corresponding blood specimen was used as a normal reference control.

Only one of 5 loci on chromosome 19q is informative. Based on LOH at D19S1182, LOH of 1p and morphology of

oligodendroglioma, findings are consistent with deletion of 19q as well. Clinical and morphologic correlation is

recommended.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of

allelic loss.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (B2)
H and E slide was examined and no microdissection was needed.

Surgical Pathology

Page 3 of 4

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

[page 3 of 4]
DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

B.

Medial frontal tumor, excision biopsy: Cluster of atypical glial cells, consistent with glioma, possibly oligodendroglioma (need to examine entire specimen). Touch preparation smears performed at

and results reported to the Physician of Record.

Senior

Staff Pathologist

Gross Description

A.

Cortical lesion, excision biopsy: SITE: cortical lesion. FIXATIVE: Formalin. TYPE: nodular bone fragment. NO.

PIECES: 1. SIZE/VOL: 0.8 cm. CASSETTES: A1-decal, NS.

B.

Received fresh, a block of cerebral cortex and adjacent white matter, 3.1 cm. Focally, grey-white matter junction is ill-defined. Serially sectioned. In total, B1-B3.

Microscopic Description

IMMUNOHISTOCHEMISTRY: The neoplastic cells are uniformly reactive with IDH1. The CD163 depicts somewhat

prominent perivascular microglia. With the MIB-1 the proliferation index is about 6% in the proliferation center, and

about 2% in the remainder tumor.

ICD-9(s): 237.5 237.5

Billing Fee Code(s):

Histo Data

Part A: Cortical lesion, excision biopsy

Taken:

Received:

Surgical Pathology

Page 4 of 4

Stain/cnt Block Ordered Comment

Decal x 1 1

H&E x 1 1

[page 4 of 4]
Part B: Medial frontal tumor, excision biopsy

Taken:

Received:

Stain/cnt Block Ordered Comment

H&E x 1 1

TPS H&E x 1 1

CD163 Vector x 1 2

H&E x 1 2

IDH1-sld x 1 2

LOH-sld x 1 2

MGMT-curis x 1 2

MIB1-DA x 1 2

H&E x 1 3

Source: NCI Genomic Data Commons file e4a23865-836c-498e-97c6-236260f260c3 (TCGA-DU-A6S2.163325D0-4CEA-4AC4-AC8A-117D492E4B06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).